Somatic mutation profile of tumor specimen TCGA-QR-A70X-01A (aliquot TCGA-QR-A70X-01A-11D-A35D-08) from TCGA case TCGA-QR-A70X, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.1 years (16,828 days).
Specimen TCGA-QR-A70X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e44a20d4-e985-47c6-ac05-567e7baf732e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70X-10A (Blood Derived Normal), aliquot TCGA-QR-A70X-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16617d05-cf95-40b4-91a9-4fee5def2eb7

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9B | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- SHC1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SLC22A11 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- KRT8 | c.522C>T p.D174= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- LMAN2L | c.805T>C p.L269= | Silent (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- QSOX2 | c.348C>T p.R116= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs1272127398; called by muse, mutect2, varscan2
